Gene-level copy-number profile of specimen HCM-STAN-1109-D13-85B from HCMI case HCM-STAN-1109-D13, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Tubulovillous adenoma, NOS; Tissue or organ of origin: Small intestine, NOS; AJCC pathologic stage: Stage 0.
Specimen HCM-STAN-1109-D13-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 8.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 4ca2f3d1-43e0-4fd1-84cb-82c96ec1a344.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-STAN-1109-D13-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,718 have no estimate.
https://portal.gdc.cancer.gov/files/9299b550-437c-48fc-aef2-8ec21fc5e1b9

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 4; copy number 1: 3,841; copy number 2: 54,974; copy number 3: 80; copy number 4: 4; copy number 5: 2.

Homozygous deletions (total copy number 0; autosomes only): 4 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr16:90,174,062–90,175,865, 1 gene (within-gene range 0–1): CICP25.
- chr21:43,414,483–43,427,131, 1 gene: SIK1.
- chr21:43,461,960–43,479,534, 2 genes (within-gene range 0–1): LINC00313, AP001048.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr16:2,091,436–2,097,026, 2 genes, copy number 5 (within-gene range 2–5): AC009065.2, AC009065.5.

Autosomal genes at a single copy (total copy number 1): 985. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
